Somatic mutation profile of tumor specimen TCGA-DD-AACZ-01A (aliquot TCGA-DD-AACZ-01A-11D-A40R-10) from TCGA case TCGA-DD-AACZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 63.6 years (23,230 days).
Specimen TCGA-DD-AACZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0b9167d-7352-4835-abc2-e164747a8a69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACZ-10A (Blood Derived Normal), aliquot TCGA-DD-AACZ-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d97233d-06f5-4342-8a27-3ad26cf2e58b

The open-access MAF lists 188 somatic variants for this specimen: 148 protein-altering or splice-affecting, 34 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 34, Nonsense Mutation 7, Splice Site 6, Frame Shift Del 3, Intron 3, 5'Flank 3, Frame Shift Ins 2, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 67/143 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD8 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.134); catalogued as rs1392149270, COSV53112792; called by muse, mutect2, varscan2
- ADAMTS19 | c.1360T>C p.C454R | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50751134; called by muse, mutect2, varscan2
- ADCY2 | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV100602028; called by muse, mutect2, varscan2
- ADD2 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781843008, COSV52457291; called by muse, mutect2, varscan2
- AHCTF1 | c.4578A>T p.E1526D (on ENST00000366508; = p.E1500D on NM_015446.5) | Missense Mutation (SNP) | VAF 66/533 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.153); catalogued as COSV100403239; called by muse, mutect2, varscan2
- AMZ1 | c.565T>A p.W189R | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100406223; called by muse, mutect2, varscan2
- ANK2 | c.671T>C p.M224T | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100000161, COSV52188660; called by muse, mutect2, varscan2
- ANO3 | c.1032+2T>A p.X344_splice | Splice Site (SNP) | VAF 27/145 reads (19%) | catalogued as COSV99881174; called by muse, mutect2
- ANO4 | c.1625T>C p.I542T (on ENST00000392977 / NM_001286615.2; = p.I507T on NM_178826.4) | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.843); catalogued as COSV100152205; called by muse, mutect2, varscan2
- ANO9 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs181550038, COSV60450003; called by muse, mutect2, varscan2
- ARID1B | c.3443A>T p.E1148V | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV51656906, COSV99267700; called by muse, mutect2, varscan2
- ATG16L2 | c.83C>A p.T28K | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV100352205; called by muse, mutect2, varscan2
- ATP13A5 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as COSV100664837; called by muse, mutect2, varscan2
- BMI1 | c.415G>C p.D139H | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100936326, COSV64958761; called by muse, mutect2
- BMP4 | c.1054A>T p.T352S | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as COSV99816803; called by muse, mutect2, varscan2
- BMS1 | c.2360A>C p.E787A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100996565; called by muse, mutect2, varscan2
- CARD11 | c.3413A>T p.K1138M | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.213); catalogued as COSV101210569; called by muse, mutect2, varscan2
- CD79B | c.301A>T p.N101Y | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99137617; called by muse, mutect2
- CLCN3 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1236240878, COSV61626304; called by muse, mutect2, varscan2
- CLIP3 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100859279; called by muse, mutect2, varscan2
- CNOT8 | c.42A>C p.E14D | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs1159366875, COSV99597118; called by muse, mutect2
- CNTN1 | c.2284C>T p.P762S | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.876); catalogued as rs566695601, COSV61636032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN3 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs139470091; called by muse, mutect2, varscan2
- COL11A2 | c.4537C>T p.R1513W (on ENST00000341947 / NM_080680.3; = p.R1406W on NM_080679.2) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs199615717, COSV59503664; called by mutect2, varscan2
- DAB2IP | c.2945A>T p.K982M (on ENST00000408936; = p.K954M on NM_032552.3) | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99404887; called by muse, mutect2, varscan2
- DDX42 | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.012); catalogued as COSV100834848; called by muse, mutect2, varscan2
- DHX8 | c.2611A>T p.I871F | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99291980; called by muse, mutect2, varscan2
- DMD | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as COSV99920131; called by muse, mutect2, varscan2
- DNAH17 | c.11117T>A p.L3706Q | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101101639; called by muse, mutect2, varscan2
- DNAH9 | c.8366A>T p.N2789I | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99304573; called by muse, mutect2, varscan2
- DYSF | c.2524A>T p.K842* | Nonsense Mutation (SNP) | VAF 33/158 reads (21%) | catalogued as COSV99244966; called by muse, mutect2, varscan2
- EDNRB | c.1597T>G p.*533Gext*18 (on ENST00000377211 / NM_001201397.1; = p.*443Gext*18 on NM_000115.5) | Nonstop Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV100526333; called by muse, mutect2, varscan2
- ELF4 | c.809+1G>C p.X270_splice | Splice Site (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100257216; called by muse, mutect2, varscan2
- EML5 | c.113A>T p.Y38F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV100715152; called by muse, mutect2, varscan2
- ESRRG | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as rs1477674632, COSV100752393; called by muse, mutect2
- ETV6 | c.391del p.S131Hfs*78 | Frame Shift Del (DEL) | VAF 30/132 reads (23%) | catalogued as COSV67154441; called by mutect2, pindel, varscan2
- FAM168A | c.107A>T p.Y36F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99291522; called by muse, mutect2, varscan2
- FER1L5 | c.5278C>T p.R1760* (on ENST00000623019; = p.R1724* on NM_001293083.2) | Nonsense Mutation (SNP) | VAF 79/312 reads (25%) | catalogued as rs769361160, COSV99383153; called by muse, mutect2, varscan2
- FRMD1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765036020, COSV99349550; called by mutect2, varscan2
- FSTL5 | c.646T>C p.C216R | Missense Mutation (SNP) | VAF 97/470 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1410022683, COSV100053350; called by muse, mutect2, varscan2
- GIT1 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99837757, COSV99837965; called by muse, mutect2, varscan2
- GNA12 | c.352C>G p.P118A | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99282414; called by muse, mutect2, varscan2
- GRHL2 | c.345A>T p.Q115H | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV99306240; called by muse, mutect2, varscan2
- GRIN2D | c.1013A>T p.Y338F | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV99616008; called by muse, mutect2, varscan2
- HECTD1 | c.3364A>G p.N1122D | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV101237315; called by muse, mutect2, varscan2
- HFM1 | c.2608A>G p.I870V | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV99645529; called by muse, mutect2, varscan2
- HGF | c.1092G>C p.W364C | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99735929; called by muse, mutect2, varscan2
- HLA-DQB1 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs281862072; called by muse, mutect2
- HOXC12 | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 82/283 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99678654; called by muse, mutect2, varscan2
- INSIG1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398230061, COSV100452874; called by muse, mutect2, varscan2
- INTS9 | c.1691G>A p.S564N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV101273813; called by muse, mutect2, varscan2
- IPMK | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.494); catalogued as COSV100880239; called by muse, mutect2
- ITGB2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100185684; called by muse, mutect2, varscan2
- ITIH5 | c.1577T>A p.L526Q | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99903927; called by muse, mutect2, varscan2
- KANK4 | c.2122A>T p.K708* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100443107; called by muse, mutect2, varscan2
- KCNB2 | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV73053625; called by muse, mutect2
- KCNC2 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 77/287 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100128379, COSV54381695; called by muse, mutect2, varscan2
- KCNH5 | c.1886A>G p.N629S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); catalogued as COSV100525630; called by muse, mutect2, varscan2
- KCNH6 | c.2912G>A p.G971D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV100120848; called by muse, mutect2, varscan2
- KIFC2 | c.2233T>C p.S745P | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.276); catalogued as rs1246540036, COSV100023615; called by muse, mutect2
- KRT74 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.376); catalogued as rs751637978, COSV99977413; called by muse, mutect2, varscan2
- LANCL1 | c.1088G>A p.C363Y | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1233531518, COSV99286166; called by muse, mutect2, varscan2
- LSS | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.382); catalogued as rs746743234, COSV100710823; called by muse, mutect2, varscan2
- MAP1A | c.5728C>T p.R1910C | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs764432579, COSV55810238; called by muse, mutect2, varscan2
- MAST4 | c.834G>T p.R278S (on ENST00000403625 / NM_001164664.2; = p.R89S on NM_015183.3) | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV99843186; called by muse, mutect2, varscan2
- MBNL1 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56826169; called by muse, mutect2, varscan2
- MICALL1 | c.2019C>G p.V673= | Splice Region (SNP) | VAF 53/107 reads (50%) | catalogued as COSV99317062; called by muse, mutect2, varscan2
- MICOS10 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100503276; called by muse, varscan2
- MTUS2 | c.3574T>A p.L1192M (on ENST00000612955 / NM_001366650.1; = p.L171M on NM_015233.6) | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100040752; called by muse, mutect2, varscan2
- MYOM2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); catalogued as rs774732664, COSV50725267; called by muse, mutect2
- NIF3L1 | c.803G>C p.R268P (on ENST00000409020 / NM_001369444.1; = p.R241P on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100677449, COSV62900105; called by muse, mutect2, varscan2
- NLRP6 | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV100380959; called by muse, mutect2, varscan2
- NOS3 | c.1296G>T p.E432D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs145811781; called by muse, mutect2, varscan2
- NOTCH4 | c.2527-2A>T p.X843_splice | Splice Site (SNP) | VAF 20/122 reads (16%) | catalogued as COSV100900454; called by muse, mutect2, varscan2
- NUTF2 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99534274; called by muse, mutect2, varscan2
- OR10K1 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99193283, COSV99193580; called by muse, mutect2, varscan2
- OR2T4 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 58/638 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100822393; called by muse, mutect2
- OR51G1 | c.278A>G p.E93G | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100429157; called by muse, mutect2, varscan2
- OR8I2 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV100135895; called by muse, mutect2, varscan2
- OXCT1 | c.78+2T>C p.X26_splice | Splice Site (SNP) | VAF 26/90 reads (29%) | catalogued as COSV99541815; called by muse, mutect2, varscan2
- PCDHB8 | c.1988T>A p.L663Q | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99176148; called by muse, mutect2, varscan2
- PCDHGA12 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 116/208 reads (56%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV99338546; called by muse, mutect2, varscan2
- PCLO | c.9844A>T p.R3282W | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100428432; called by muse, mutect2, varscan2
- PDIA4 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV99618329; called by muse, mutect2
- PIK3R4 | c.2846A>T p.Q949L | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV100768280; called by muse, mutect2, varscan2
- PIKFYVE | c.2137T>G p.Y713D | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100010027; called by muse, mutect2
- PIWIL2 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV100769261; called by muse, mutect2, varscan2
- PLEKHA1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 110/263 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1303067486, COSV100935443; called by muse, mutect2, varscan2
- PLTP | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as rs766473918, COSV100819067; called by muse, mutect2, varscan2
- PLXNA4 | c.2980T>A p.C994S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100322926; called by muse, mutect2, varscan2
- PROM1 | c.632A>T p.Q211L | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV101477057; called by muse, mutect2, varscan2
- PRUNE2 | c.6760A>T p.S2254C | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV100944273; called by muse, mutect2, varscan2
- PSIP1 | c.949A>C p.K317Q | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.276); catalogued as COSV101050904; called by muse, mutect2, varscan2
- PTPN14 | c.2071C>A p.Q691K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100872395, COSV65284930; called by mutect2, varscan2
- RBBP8NL | c.887T>A p.L296Q | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99436372; called by muse, mutect2, varscan2
- RETREG1 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100103915; called by muse, mutect2, varscan2
- ROS1 | c.6896C>G p.S2299C | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV100876600, COSV63861607; called by muse, mutect2, varscan2
- RPP21 | c.437-2A>T p.X146_splice (on ENST00000428040; = p.X123_splice on NM_024839.4) | Splice Site (SNP) | VAF 49/128 reads (38%) | catalogued as COSV100935645; called by muse, mutect2, varscan2
- RUFY3 | c.1300A>T p.N434Y | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99886956; called by muse, mutect2, varscan2
- RUNX3 | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.824); catalogued as COSV100136694; called by muse, mutect2, varscan2
- SCEL | c.607C>A p.Q203K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV100582650; called by muse, mutect2, varscan2
- SCRIB | c.966C>A p.N322K | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100252740; called by muse, varscan2
- SEL1L3 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs749812534, COSV99339652; called by muse, mutect2, varscan2
- SERPINB4 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV100345474; called by muse, mutect2, varscan2
- SIX5 | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.818); catalogued as rs1162093037, COSV99352814; called by muse, mutect2, varscan2
- SLC10A5 | c.356A>T p.K119M | Missense Mutation (SNP) | VAF 32/226 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV101594247; called by muse, mutect2, varscan2
- SLC26A2 | c.1768A>T p.I590L | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99640032; called by muse, mutect2, varscan2
- SLC39A6 | c.2183A>T p.Q728L | Missense Mutation (SNP) | VAF 185/358 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99309412; called by muse, mutect2, varscan2
- SLC44A1 | c.1715T>A p.L572Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100570233; called by muse, mutect2, varscan2
- SLC9C1 | c.1253T>G p.I418S | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV99997463; called by muse, mutect2
- SMC5 | c.2161A>T p.M721L | Missense Mutation (SNP) | VAF 86/441 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.018); catalogued as COSV100746990; called by muse, mutect2, varscan2
- SMURF2 | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.059); catalogued as COSV99300419; called by muse, mutect2, varscan2
- SNRNP200 | c.4703A>C p.Q1568P | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100107273; called by muse, mutect2, varscan2
- SOX30 | c.1835T>C p.F612S | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99398226; called by muse, mutect2, varscan2
- SPATA9 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1338226705, COSV99174134; called by muse, mutect2, varscan2
- SSNA1 | c.55A>G p.I19V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs1364484728, COSV100118934; called by muse, mutect2, varscan2
- SYCP1 | c.2656T>A p.F886I | Missense Mutation (SNP) | VAF 74/407 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.247); catalogued as COSV101050794; called by muse, mutect2, varscan2
- TENM4 | c.8242T>A p.Y2748N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99572036; called by muse, mutect2, varscan2
- TENM4 | c.5489G>A p.R1830Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs925239438, COSV53647724; called by muse, mutect2, varscan2
- TGM6 | c.2029A>C p.S677R | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99171696; called by muse, mutect2, varscan2
- TLE4 | c.1277C>G p.P426R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as COSV99511405; called by muse, mutect2, varscan2
- TMBIM1 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99297818; called by muse, mutect2, varscan2
- TMEM135 | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100449431; called by muse, mutect2, varscan2
- TOGARAM1 | c.2105T>G p.V702G | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100817871; called by muse, mutect2, varscan2
- TP53 | c.788_789insG p.N263Kfs*9 | Frame Shift Ins (INS) | VAF 30/66 reads (45%) | catalogued as COSV52826458; called by mutect2, pindel*, varscan2
- TRANK1 | c.2309A>T p.Q770L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as COSV100081856; called by muse, mutect2, varscan2
- TRPM7 | c.3515A>G p.D1172G | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV100539484; called by muse, mutect2, varscan2
- TRPS1 | c.794T>A p.L265* (on ENST00000220888 / NM_001330599.2; = p.L278* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/294 reads (9%) | catalogued as COSV99629010; called by muse, mutect2
- TSBP1 | c.869A>T p.K290M (on ENST00000617061; = p.K293M on NM_006781.5) | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100898726; called by muse, varscan2
- TTC12 | c.596A>T p.K199M | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100132897; called by muse, mutect2, varscan2
- TTN | c.67686T>A p.Y22562* (on ENST00000591111; = p.Y15138* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 31/144 reads (22%) | catalogued as COSV100598547; called by muse, mutect2, varscan2
- TTN | c.35970G>T p.K11990N (on ENST00000591111; = p.K4566N on NM_003319.4) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | PolyPhen probably damaging (0.994); catalogued as COSV100598549, COSV100628108; called by muse, mutect2, varscan2
- TWIST1 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.019); catalogued as rs1229160500, COSV99642998; called by muse, mutect2, varscan2
- TXN2 | c.388G>C p.V130L | Missense Mutation (SNP) | VAF 51/74 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99340381; called by muse, mutect2, varscan2
- USP24 | c.2373A>T p.L791F | Missense Mutation (SNP) | VAF 108/307 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV99599044; called by muse, mutect2, varscan2
- USP8 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 123/521 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV100208816; called by muse, mutect2, varscan2
- VWA5A | c.2132T>C p.I711T | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100827749; called by muse, mutect2, varscan2
- WDR61 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV51216609, COSV99144532; called by muse, mutect2, varscan2
- WIF1 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV99682637; called by muse, mutect2, varscan2
- ZBTB40 | c.1954A>T p.K652* | Nonsense Mutation (SNP) | VAF 22/110 reads (20%) | catalogued as COSV100988835; called by muse, mutect2, varscan2
- ZFPM2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 141/630 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1240193228, COSV101342977, COSV101343243; called by muse, mutect2, varscan2
- ZNF394 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.111); catalogued as rs1466170208, COSV100529818; called by muse, mutect2, varscan2
- ZNF628 | c.2579A>C p.Q860P | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99219828; called by muse, mutect2, varscan2
- ZWINT | c.257-2A>T p.X86_splice | Splice Site (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100571484; called by muse, mutect2, varscan2
- BBS4 | c.639dup p.Q214Tfs*10 | Frame Shift Ins (INS) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- CD1B | c.917del p.L306Wfs*3 | Frame Shift Del (DEL) | VAF 135/495 reads (27%) | called by mutect2, varscan2
- FAM78A | c.298_323del p.Y100Vfs*52 | Frame Shift Del (DEL) | VAF 13/96 reads (14%) | called by mutect2, pindel
- BMPER | c.1353G>A p.A451= | Silent (SNP) | VAF 80/194 reads (41%) | catalogued as COSV51821969; called by muse, varscan2
- C14orf119 | c.408A>G p.T136= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99399201; called by muse, mutect2, varscan2
- CACNA1G | c.1956C>T p.S652= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100661320; called by muse, mutect2
- CDC23 | c.1389A>G p.G463= | Silent (SNP) | VAF 62/129 reads (48%) | catalogued as COSV101203091; called by muse, mutect2, varscan2
- COL25A1 | c.1620T>A p.P540= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV101211265; called by muse, mutect2, varscan2
- CPD | c.3117T>C p.D1039= | Silent (SNP) | VAF 49/131 reads (37%) | catalogued as COSV99852541; called by muse, mutect2, varscan2
- CWH43 | c.642A>G p.G214= | Silent (SNP) | VAF 46/209 reads (22%) | catalogued as COSV99892961; called by muse, mutect2, varscan2
- DCAF12L1 | c.57C>T p.D19= | Silent (SNP) | VAF 43/105 reads (41%) | catalogued as COSV64422675; called by muse, mutect2, varscan2
- DDX21 | c.285G>A p.L95= | Silent (SNP) | VAF 221/513 reads (43%) | catalogued as COSV100826480, COSV62555334; called by muse, mutect2, varscan2
- DISP2 | c.2352C>A p.G784= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV51145547; called by muse, mutect2, varscan2
- ELN | c.78T>A p.P26= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99332356; called by muse, mutect2, varscan2
- GDI2 | c.138A>C p.I46= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV101200740; called by muse, mutect2, varscan2
- GJB7 | c.222C>T p.V74= | Silent (SNP) | VAF 52/194 reads (27%) | catalogued as COSV99738100; called by muse, mutect2, varscan2
- GUCY2D | c.1326A>T p.A442= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV99643805; called by muse, mutect2, varscan2
- IPO8 | c.213A>T p.R71= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV99804851; called by muse, mutect2, varscan2
- ITGA2 | c.2754A>G p.E918= | Silent (SNP) | VAF 41/191 reads (21%) | catalogued as COSV99670371; called by muse, mutect2, varscan2
- ITGA5 | c.1497C>T p.L499= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV99516399; called by muse, mutect2, varscan2
- KRT3 | c.372C>T p.G124= | Silent (SNP) | VAF 44/156 reads (28%) | catalogued as rs1382093860, COSV100526925; called by muse, mutect2, varscan2
- LMTK3 | c.3243C>T p.N1081= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99540068; called by muse, mutect2, varscan2
- MARCO | c.804G>T p.G268= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as rs1001316519, COSV100503248, COSV59058651; called by muse, mutect2, varscan2
- MFAP2 | c.48G>T p.L16= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as COSV100977596; called by muse, mutect2, varscan2
- MOSPD2 | c.387A>T p.I129= | Silent (SNP) | VAF 208/450 reads (46%) | catalogued as COSV100996712; called by muse, mutect2, varscan2
- MRC1 | c.3867T>G p.L1289= | Silent (SNP) | VAF 224/877 reads (26%) | called by muse, mutect2, varscan2
- NAIP | c.114A>T p.L38= | Silent (SNP) | VAF 26/165 reads (16%) | catalogued as COSV99519183; called by muse, mutect2, varscan2
- NHLH2 | c.75C>T p.G25= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs766590445, COSV100204919; called by muse, mutect2, varscan2
- POU6F2 | c.879T>A p.P293= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV101302518; called by muse, mutect2, varscan2
- RUNX3 | c.738C>A p.R246= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV100136695; called by muse, mutect2, varscan2
- SEMA3E | c.1971A>G p.V657= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs780529361, COSV100317594; called by muse, mutect2, varscan2
- SLC34A2 | c.429T>A p.P143= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV101158239; called by muse, mutect2, varscan2
- TAAR9 | c.108C>T p.Y36= | Silent (SNP) | VAF 24/165 reads (15%) | catalogued as rs1554255087, COSV71512244; called by muse, mutect2, varscan2
- TRPS1 | c.1437T>C p.S479= (on ENST00000220888 / NM_001330599.2; = p.S492= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/179 reads (9%) | catalogued as COSV99629008; called by muse, mutect2
- USPL1 | c.429A>G p.G143= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV99687073; called by muse, mutect2
- WDR62 | c.54G>A p.L18= | Silent (SNP) | VAF 98/149 reads (66%) | catalogued as rs1174676813, COSV99495672; called by muse, mutect2, varscan2
- ZNF391 | c.477C>T p.H159= | Silent (SNP) | VAF 80/199 reads (40%) | catalogued as COSV99772449; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457704 A>G | 5'Flank (SNP) | VAF 54/604 reads (9%) | called by muse, mutect2, varscan2
- HSPA2 | chr14:64531873 G>A | 5'Flank (SNP) | VAF 18/98 reads (18%) | catalogued as COSV100704001; called by muse, mutect2, varscan2
- NIN | c.-21-1229A>T | Intron (SNP) | VAF 26/118 reads (22%) | catalogued as COSV99812123; called by muse, mutect2, varscan2
- RHOT1 | c.1739+2848C>G | Intron (SNP) | VAF 7/83 reads (8%) | catalogued as COSV100446963; called by muse, mutect2
- SGCD | c.696+58C>A | Intron (SNP) | VAF 44/438 reads (10%) | catalogued as rs760611730, COSV100549003; called by muse, mutect2
- TMEM132E | chr17:34578885 T>A | 5'Flank (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
